Somatic mutation profile of tumor specimen MP2PRT-PATGPJ-TMP1-A (aliquot MP2PRT-PATGPJ-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATGPJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,730 days).
Specimen MP2PRT-PATGPJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add9db59-2108-479e-9321-94ace053566e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGPJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGPJ-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cd9ed44-f21d-468b-bb43-e9994d0f8ac7

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.2617G>A p.E873K (on ENST00000502732 / NM_007314.4; = p.E858K on NM_005158.5) | Missense Mutation (SNP) | VAF 97/396 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.139); catalogued as rs778722832; called by muse, mutect2, varscan2
- CBLN1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 224/804 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV54653446, COSV54654056; called by muse, mutect2, varscan2
- CER1 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.923); catalogued as rs759414494; called by muse, mutect2, varscan2
- CYP2F1 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1243044452, COSV58528406; called by muse, mutect2, varscan2
- GPR25 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 262/635 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as COSV100421691; called by muse, mutect2, varscan2
- ITGB3 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 136/493 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs763127353; called by muse, mutect2, varscan2
- MMP1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs201865180, COSV100188027; called by muse, mutect2, varscan2
- PCDH1 | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 245/873 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as rs767636294, COSV54618344, COSV54619295; called by muse, mutect2, varscan2
- SLC7A14 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 126/377 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs749136940; called by muse, mutect2, varscan2
- TOGARAM2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs768249766; called by muse, mutect2, varscan2
- UNC13A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as rs566299244, COSV53210618; called by muse, varscan2
- ABL2 | c.2379G>C p.E793D (on ENST00000502732 / NM_007314.4; = p.E778D on NM_005158.5) | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDAH2 | c.575_576insGGGCTGC p.Q193Gfs*25 | Frame Shift Ins (INS) | VAF 116/454 reads (26%) | called by pindel, varscan2
- ELFN1 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 241/498 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ETV6 | c.142_143insATAATTGAATAATGGA p.I48Nfs*3 | Nonsense Mutation (INS) | VAF 66/347 reads (19%) | called by mutect2, pindel, varscan2
- NHSL2 | c.422C>A p.T141N (on ENST00000510661; = p.T507N on NM_001013627.2) | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TAF11L13 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 169/519 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ABL2 | c.2865G>T p.G955= (on ENST00000502732 / NM_007314.4; = p.G940= on NM_005158.5) | Silent (SNP) | VAF 65/295 reads (22%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1755G>A p.K585= | Silent (SNP) | VAF 98/335 reads (29%) | catalogued as rs577564216; called by muse, mutect2, varscan2
- DHRS7 | c.711G>A p.V237= | Silent (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- HSPBP1 | c.912G>A p.P304= | Silent (SNP) | VAF 115/297 reads (39%) | catalogued as rs142524191; called by muse, varscan2
- IGSF9 | c.2550C>T p.D850= (on ENST00000368094 / NM_001135050.2; = p.D834= on NM_020789.4) | Silent (SNP) | VAF 24/527 reads (5%) | catalogued as rs765337980; called by muse, mutect2
- MUC17 | c.3309A>G p.L1103= | Silent (SNP) | VAF 121/361 reads (34%) | called by muse, mutect2, varscan2
- NBPF4 | c.1737C>T p.S579= | Silent (SNP) | VAF 48/243 reads (20%) | called by muse, mutect2, varscan2
- PALLD | c.3243C>T p.H1081= (on ENST00000505667 / NM_001166108.2; = p.H1064= on NM_016081.4) | Silent (SNP) | VAF 97/497 reads (20%) | catalogued as rs779615947; called by muse, mutect2, varscan2
- SPC24 | c.390A>G p.T130= | Silent (SNP) | VAF 103/264 reads (39%) | called by muse, mutect2, varscan2
